CCDI case PBBMFU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/837bdee2-71ff-4da2-90a2-a156d045c4c2

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.9 years (2,139 days).

Biospecimens (3 samples)
- Sample 0DC7SV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DC7T6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DC7TH: Tissue type: Tumor; Specimen type: Solid Tissue.
